Gene-level copy-number profile of tumor specimen TCGA-DU-6405-01A from TCGA case TCGA-DU-6405, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 51.2 years (18,686 days).
Specimen TCGA-DU-6405-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.a61e91e8-8948-4831-a22d-98cccc3ef527.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DU-6405-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b5e4a56f-6dbd-4203-87ea-dd5bd414ff6f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 107; copy number 1: 36; copy number 2: 4,153; copy number 3: 494; copy number 4: 52,905; copy number 6: 2,105; copy number 7: 12; copy number 38: 6; copy number 40: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DU-6405-01A-11D-1704-01): tumor purity 0.87, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 107 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:171,494,684–176,277,571, 56 genes: AC074254.2, LINC02174, AC074254.1, GALNTL6, AC108064.1, AC105285.1, RN7SL253P, GALNT7, MIR548T, AC097534.1, HMGB2, SAP30-DT, SAP30, SCRG1, AC093849.4, RPL5P11, AC093849.3, RNU6-1096P, AC093849.1, AC093849.2, HAND2, HAND2-AS1, MORF4, RANP6, LINC02269, AC106895.1, AC106895.2, LINC02268, AC012055.1, AC012055.2, FBXO8, CEP44, AC116616.1, MIR4276, HPGD, AC096751.2, AC096751.1, GLRA3, ADAM29, AC105914.1, AC105914.2, AC022325.1, AC022325.2, AC095050.2, AC095050.1, AC131094.1, TSEN2P1, ADAM20P2, GPM6A, AC097537.1, AC110794.1, MARK2P4, WDR17, AC093605.1, SPATA4, ASB5.
- chr4:176,631,392–177,681,381, 13 genes (within-gene range 0–2): AC093801.2, AC093801.1, VEGFC, AC097518.2, AC092673.1, LINC02509, RN7SKP136, AC097518.1, NEIL3, AC027627.1, AGA, AC078881.1, RNA5SP172.
- chr4:177,728,757–178,028,971, 2 genes (within-gene range 0–2): LINC01098, LINC01099.
- chr4:178,286,695–182,803,024, 25 genes (within-gene range 0–2): AC095041.1, RNA5SP173, AC017087.1, AC018710.1, AC020551.1, AC021193.1, AC108169.1, AC096747.1, NDUFB5P1, AC104803.1, LINC00290, AC019235.1, LINC02500, AC093840.1, AC093840.2, AC084741.1, TEMN3-AS1, RN7SKP13, TENM3-AS1, CCNHP1, TENM3, AC108142.1, MIR1305, RNU2-34P, RN7SKP67.
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,933,699–54,938,184, 1 gene, copy number 40: AC006971.1.
- chr7:55,179,750–55,433,742, 6 genes, copy number 38: EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.

Autosomal genes at a single copy (total copy number 1): 36. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
